Somatic mutation profile of tumor specimen TCGA-CC-A3MC-01A (aliquot TCGA-CC-A3MC-01A-11D-A22F-10) from TCGA case TCGA-CC-A3MC, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 54.9 years (20,067 days).
Specimen TCGA-CC-A3MC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d12223f0-1672-478b-8d38-b7fab7570e11.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CC-A3MC-10A (Blood Derived Normal), aliquot TCGA-CC-A3MC-10A-01D-A22F-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d938ab83-709f-48ce-8718-5ef67402bab9

The open-access MAF lists 112 somatic variants for this specimen: 87 protein-altering or splice-affecting, 22 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 22, Nonsense Mutation 8, Frame Shift Del 4, Splice Site 3, Frame Shift Ins 2, Intron 2, Splice Region 2, Translation Start Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACCS | c.432A>C p.E144D | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs752846711, COSV55459440; called by muse, mutect2, varscan2
- ACP3 | c.556-2A>C p.X186_splice | Splice Site (SNP) | VAF 18/73 reads (25%) | catalogued as COSV60487564; called by muse, mutect2, varscan2
- ALG6 | c.562C>A p.L188I | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.477); catalogued as COSV54766482; called by muse, mutect2
- BCKDK | c.283del p.Q95Sfs*6 | Frame Shift Del (DEL) | VAF 21/81 reads (26%) | catalogued as COSV54894290; called by mutect2, pindel, varscan2
- BIRC6 | c.1648G>T p.E550* | Nonsense Mutation (SNP) | VAF 5/96 reads (5%) | catalogued as COSV70203340; called by muse, mutect2
- C11orf80 | c.664A>G p.I222V | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.12); catalogued as rs749060869, COSV60930406; called by muse, mutect2, varscan2
- CAMTA1 | c.3451G>A p.A1151T | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57915981; called by muse, mutect2, varscan2
- CAP2 | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.104); catalogued as COSV57734844; called by muse, mutect2, varscan2
- CAPZA1 | c.139A>T p.R47W | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54146440; called by muse, mutect2, varscan2
- CD55 | c.952A>C p.T318P | Missense Mutation (SNP) | VAF 76/152 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV58577600; called by muse, mutect2, varscan2
- CD99 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.994); catalogued as rs188016181, COSV66989201; called by muse, mutect2, varscan2
- CLCN2 | c.2294A>G p.E765G | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1186891303, COSV55603012; called by muse, mutect2, varscan2
- CLTC | c.2995G>C p.D999H | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV52250303; called by muse, mutect2, varscan2
- CPN1 | c.703C>T p.R235* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as COSV64942590; called by muse, mutect2, varscan2
- CPS1 | c.2162G>T p.R721L | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM114345, COSV51818176, COSV51823423; called by muse, mutect2, varscan2
- DCSTAMP | c.680C>A p.T227N | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52579032; called by muse, mutect2, varscan2
- DGKE | c.761A>G p.K254R | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as COSV52350683; called by muse, mutect2, varscan2
- DISP2 | c.2663A>T p.Q888L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV51131147; called by muse, mutect2, varscan2
- EDNRA | c.370C>G p.L124V | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as COSV60099201, COSV60100389; called by muse, mutect2
- EIF4H | c.524G>T p.R175L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.63); catalogued as COSV56082846, COSV99733519; called by muse, mutect2, varscan2
- EIF5A | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated (0.06); PolyPhen benign (0.145); catalogued as rs769669056, COSV59746693; called by muse, mutect2, varscan2
- ERICH3 | c.2942C>T p.A981V | Missense Mutation (SNP) | VAF 52/153 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV58613298; called by muse, mutect2, varscan2
- FOLR2 | c.320T>A p.L107Q | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53352068; called by muse, mutect2, varscan2
- FOXB1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV68526262; called by muse, mutect2
- GGT7 | c.237C>G p.S79R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV60541884; called by muse, mutect2, varscan2
- GNB2 | c.469A>G p.I157V | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.601); catalogued as rs1446422421, COSV51944898; called by muse, mutect2, varscan2
- GPRIN1 | c.540G>A p.M180I | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV56142429; called by muse, mutect2
- HCFC1 | c.1605G>T p.T535= | Splice Region (SNP) | VAF 25/42 reads (60%) | catalogued as COSV60075231; called by muse, mutect2, varscan2
- HOXA3 | c.77A>G p.Y26C | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57828007; called by muse, mutect2
- HOXA6 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1454642111, COSV56074072; called by muse, mutect2
- IL20RA | c.871A>G p.I291V | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as COSV57359568; called by muse, mutect2, varscan2
- INPPL1 | c.2211A>G p.K737= | Splice Region (SNP) | VAF 14/58 reads (24%) | catalogued as rs1168735661, COSV53357705; called by muse, mutect2, varscan2
- INSIG1 | c.413-1G>C p.X138_splice | Splice Site (SNP) | VAF 21/65 reads (32%) | catalogued as COSV60920833; called by muse, mutect2, varscan2
- LAMP1 | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 44/78 reads (56%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV60212338; called by muse, mutect2, varscan2
- LCE5A | c.22C>A p.Q8K | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.026); catalogued as rs902393265, COSV57499760, COSV57501168; called by muse, mutect2, varscan2
- LINS1 | c.1271A>T p.H424L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV59080147; called by muse, mutect2, varscan2
- LRRIQ3 | c.239A>C p.H80P | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs552021191, COSV63047565; called by muse, mutect2, varscan2
- MAP1A | c.1505C>T p.P502L | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as COSV55811139; called by muse, mutect2, varscan2
- MYH15 | c.3203A>C p.E1068A | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV56315614; called by muse, mutect2, varscan2
- MYO1E | c.1357A>C p.K453Q | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); catalogued as COSV55691739; called by muse, mutect2, varscan2
- MYZAP | c.1168C>G p.Q390E | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.086); catalogued as COSV51094126; called by muse, mutect2, varscan2
- NDUFA5 | c.28G>T p.G10C | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63252023, COSV63252225; called by muse, mutect2, varscan2
- NEU2 | c.872A>T p.Q291L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.081); catalogued as COSV52093488; called by muse, mutect2, varscan2
- NOBOX | c.1399C>A p.P467T | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56196328; called by muse, mutect2, varscan2
- NOTCH3 | c.1177G>C p.D393H | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54642497, COSV54649251; called by muse, mutect2, varscan2
- NOX4 | c.1030C>G p.P344A | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54459631; called by muse, mutect2, varscan2
- OLFM3 | c.260G>T p.R87L (on ENST00000338858 / NM_001288821.1; = p.R67L on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs748816968, COSV58801462; called by muse, mutect2, varscan2
- OR10G7 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs764931043, COSV57867971; called by muse, mutect2
- PCARE | c.1113G>T p.W371C | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as COSV59056438; called by muse, mutect2, varscan2
- PCDHGB5 | c.844T>C p.Y282H | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV53993988; called by muse, mutect2, varscan2
- PHTF2 | c.967A>G p.T323A (on ENST00000248550 / NM_001366089.1; = p.T285A on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV50333830; called by muse, mutect2, varscan2
- PKD1 | c.6910A>G p.T2304A | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as COSV51921416; called by muse, mutect2, varscan2
- PKN1 | c.1494A>C p.Q498H | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV54400937; called by muse, mutect2, varscan2
- PLXNA4 | c.1552G>T p.E518* | Nonsense Mutation (SNP) | VAF 30/72 reads (42%) | catalogued as COSV58121460, COSV58146496; called by muse, mutect2, varscan2
- POT1 | c.1396C>T p.L466F | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV62932781; called by mutect2, varscan2
- PRAMEF14 | c.1218G>T p.K406N | Missense Mutation (SNP) | VAF 10/209 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV100577307; called by muse, mutect2
- PRMT1 | c.501C>A p.C167* | Nonsense Mutation (SNP) | VAF 21/84 reads (25%) | catalogued as COSV67160076; called by muse, mutect2, varscan2
- PRMT6 | c.781G>T p.A261S | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs762278719, COSV63655993; called by muse, mutect2, varscan2
- PSMB6 | c.713C>A p.P238H | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV54513152; called by muse, mutect2, varscan2
- PSMD14 | c.347C>G p.P116R | Missense Mutation (SNP) | VAF 54/254 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68833457; called by muse, mutect2, varscan2
- SEC31B | c.2579A>G p.N860S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV64844804, COSV64845167; called by muse, mutect2, varscan2
- SH2B1 | c.268C>A p.P90T | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.025); catalogued as COSV100451299; called by muse, mutect2
- SPEN | c.6595G>T p.A2199S | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs550359408, COSV65365311; called by muse, mutect2, varscan2
- STAM | c.337G>A p.V113I | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.946); catalogued as COSV66325687; called by muse, mutect2, varscan2
- SURF4 | c.152A>T p.Q51L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64339066; called by muse, mutect2, varscan2
- SUSD3 | c.619G>A p.G207R | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV64937383; called by muse, mutect2, varscan2
- SVIL | c.2182C>T p.R728C (on ENST00000355867 / NM_021738.3; = p.R334C on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757759541, COSV63440461; called by muse, mutect2, varscan2
- TANC2 | c.3067C>T p.R1023* | Nonsense Mutation (SNP) | VAF 41/129 reads (32%) | catalogued as COSV67338282; called by muse, mutect2, varscan2
- TCF7L2 | c.914A>T p.H305L (on ENST00000355995 / NM_001367943.1; = p.H282L on NM_030756.5) | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV53345215; called by muse, mutect2, varscan2
- TECTA | c.5318G>T p.R1773L | Missense Mutation (SNP) | VAF 35/191 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.168); catalogued as COSV50701874, COSV50756999; called by muse, mutect2, varscan2
- TEX44 | c.985C>A p.R329S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV58355209; called by muse, mutect2, varscan2
- TMEM215 | c.374G>A p.S125N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV61363845; called by muse, mutect2, varscan2
- TMF1 | c.719A>G p.N240S | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.659); catalogued as COSV68375232; called by muse, mutect2, varscan2
- TNRC6B | c.2218C>T p.Q740* | Nonsense Mutation (SNP) | VAF 54/110 reads (49%) | catalogued as COSV57299962; called by muse, mutect2, varscan2
- TTBK1 | c.2197G>T p.E733* | Nonsense Mutation (SNP) | VAF 24/63 reads (38%) | catalogued as COSV52494368; called by muse, mutect2, varscan2
- TUBA3D | c.214C>A p.P72T | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.153); catalogued as COSV100342975; called by muse, mutect2, varscan2
- UBXN4 | c.460C>T p.L154F | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.74); PolyPhen benign (0.289); catalogued as rs964000481, COSV55634540; called by muse, mutect2, varscan2
- WASHC4 | c.881C>G p.S294* | Nonsense Mutation (SNP) | VAF 37/110 reads (34%) | catalogued as COSV59891080; called by muse, mutect2, varscan2
- ZNF644 | c.808A>G p.M270V | Missense Mutation (SNP) | VAF 74/213 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV61349201; called by muse, varscan2
- ZNF804B | c.1352G>T p.G451V | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60842287; called by muse, mutect2, varscan2
- ZNF98 | c.343T>A p.C115S | Missense Mutation (SNP) | VAF 102/276 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV63338314; called by muse, mutect2, varscan2
- CYB5A | c.84_96del p.I29Rfs*5 | Frame Shift Del (DEL) | VAF 14/61 reads (23%) | called by mutect2, pindel, varscan2
- ECPAS | c.1129del p.C377Vfs*2 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | called by mutect2, pindel, varscan2
- KIAA1217 | c.2540_2556del p.E847Gfs*99 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | called by mutect2, pindel, varscan2
- LMCD1 | c.108_131+15del p.X36_splice | Splice Site (DEL) | VAF 18/92 reads (20%) | called by mutect2, pindel
- ROBO1 | c.26dup p.L9Ffs*24 | Frame Shift Ins (INS) | VAF 11/92 reads (12%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.6889dup p.R2297Kfs*5 | Frame Shift Ins (INS) | VAF 62/149 reads (42%) | called by mutect2, pindel, varscan2
- AFMID | c.51G>A p.K17= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs745962259, COSV56960491; called by muse, mutect2, varscan2
- ANKRD11 | c.807G>A p.T269= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs149525788, COSV56366831; called by muse, mutect2, varscan2
- CEP128 | c.1830T>G p.A610= | Silent (SNP) | VAF 15/138 reads (11%) | catalogued as rs1399947641, COSV55384728; called by muse, mutect2, varscan2
- CLPX | c.1901A>G p.*634= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV55645731; called by muse, mutect2, varscan2
- COL5A1 | c.1446T>C p.P482= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV65672585; called by muse, mutect2
- COX10 | c.321A>G p.L107= | Silent (SNP) | VAF 44/100 reads (44%) | catalogued as rs1405019605, COSV55407179; called by muse, mutect2, varscan2
- CRACDL | c.312C>T p.D104= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as rs746340837, COSV67406758; called by muse, mutect2, varscan2
- EMILIN2 | c.1404C>T p.C468= | Silent (SNP) | VAF 40/96 reads (42%) | catalogued as rs994560353, COSV54425785; called by muse, mutect2, varscan2
- FANCD2 | c.3351C>T p.Y1117= | Silent (SNP) | VAF 43/145 reads (30%) | catalogued as rs566518051, COSV55042563; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FHL5 | c.402A>G p.R134= | Silent (SNP) | VAF 45/122 reads (37%) | catalogued as COSV58739225; called by muse, mutect2, varscan2
- IFT43 | c.372C>A p.I124= (on ENST00000314067 / NM_001102564.3; = p.I129= on NM_052873.3) | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV53140173; called by muse, mutect2
- MICAL3 | c.1656C>G p.A552= | Silent (SNP) | VAF 51/158 reads (32%) | catalogued as COSV52901975; called by muse, mutect2, varscan2
- NEIL1 | c.246C>T p.S82= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs1169278956, COSV61833860; called by muse, mutect2, varscan2
- NLRC4 | c.2517C>T p.I839= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as COSV61593930; called by muse, mutect2, varscan2
- RANBP3 | c.648A>G p.A216= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as rs761477217, COSV50383970; called by muse, mutect2, varscan2
- RYR3 | c.3735C>A p.V1245= | Silent (SNP) | VAF 43/103 reads (42%) | catalogued as COSV66801739; called by muse, mutect2, varscan2
- SIPA1L3 | c.3429A>G p.V1143= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV55920054; called by muse, mutect2, varscan2
- SLC16A10 | c.1278C>T p.F426= | Silent (SNP) | VAF 79/190 reads (42%) | catalogued as COSV64354997; called by muse, mutect2, varscan2
- STAB1 | c.7635C>T p.D2545= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as COSV58740460; called by muse, mutect2, varscan2
- TAS2R38 | c.234T>C p.L78= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as COSV71885790; called by muse, mutect2, varscan2
- TSLP | c.225C>T p.C75= | Silent (SNP) | VAF 17/132 reads (13%) | catalogued as rs1561691152, COSV61292099; called by muse, mutect2, varscan2
- TSSK1B | c.798C>A p.I266= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV66815738; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81156909 C>T | 3'Flank (SNP) | VAF 24/41 reads (59%) | catalogued as rs375813573; called by muse, mutect2, varscan2
- MTUS1 | c.2449+1778T>C | Intron (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- NACA | c.70+4633C>A | Intron (SNP) | VAF 11/113 reads (10%) | catalogued as COSV63271485; called by muse, mutect2
